Gene-level copy-number profile of tumor specimen TCGA-LN-A4A4-01A from TCGA case TCGA-LN-A4A4, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage III; Tumor grade: GX; Age at diagnosis: 36.7 years (13,419 days).
Specimen TCGA-LN-A4A4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.8f56aa2e-6c9a-450e-a11e-979ea05b7143.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-LN-A4A4-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/edad0686-cb8b-4d61-bb4b-3f5bd3a6da28

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 4,526; copy number 2: 33,573; copy number 3: 13,747; copy number 4: 3,859; copy number 5: 2,678; copy number 6: 721; copy number 7: 277; copy number 8: 343; copy number 10: 17; copy number 13: 38; copy number 20: 30.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-LN-A4A4-01A-11D-A25X-01): tumor purity 0.64, ploidy 2.57, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:235,773,855–235,882,493, 2 genes: AC064874.1, TMSB10P1.
- chr9:21,994,139–22,128,103, 5 genes (within-gene range 0–2): CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,104 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:7,519,741–10,243,745, 64 genes, copy number 5 (broad region; genes not listed).
- chr3:24,687,919–25,873,748, 17 genes, copy number 6 (within-gene range 1–6): AC092422.1, RN7SL216P, RNA5SP125, RARB, CFL1P7, RNA5SP126, H3P10, AC093416.1, TOP2B, AC093416.2, MIR4442, CRIP1P2, NGLY1, AC092798.1, TAF9BP1, OXSM, LINC00692.
- chr3:166,670,029–180,871,005, 215 genes, copy number 6–8 (broad region; genes not listed).
- chr3:180,887,677–180,888,075, 1 gene, copy number 8: AC108734.1.
- chr7:70,972–40,134,622, 723 genes, copy number 5 (broad region; genes not listed).
- chr7:40,151,613–40,154,151, 1 gene, copy number 5: THUMPD3P1.
- chr7:41,667,168–57,837,046, 349 genes, copy number 5 (broad region; genes not listed).
- chr7:73,328,161–73,358,637, 1 gene, copy number 7 (within-gene range 2–7): FKBP6.
- chr7:73,403,788–74,602,605, 32 genes, copy number 7 (within-gene range 2–7): Y_RNA, FZD9, BAZ1B, RNU6-1198P, BCL7B, TBL2, MLXIPL, AC005089.1, VPS37D, DNAJC30, BUD23, STX1A, MIR4284, RN7SL265P, ABHD11-AS1, ABHD11, CLDN3, CLDN4, METTL27, TMEM270, AC099398.1, ELN, ELN-AS1, LIMK1, EIF4H, MIR590, LAT2, RFC2, AC005081.1, CLIP2, GTF2IRD1, RNA5SP233.
- chr7:106,372,251–109,326,315, 45 genes, copy number 8 (within-gene range 3–8): AC004917.1, AC005050.3, AC005050.1, AC005050.2, CCDC71L, LINC02577, RNA5SP236, PIK3CG, PRKAR2B, PRKAR2B-AS1, HBP1, AC004492.1, COG5, AC002381.1, GPR22, DUS4L, DUS4L-BCAP29, AC004839.2, BCAP29, AC004839.1, WBP1LP2, BANF1P5, SLC26A4-AS1, SLC26A4, AC002467.1, CBLL1, SLC26A3, PIGCP2, DLD, LAMB1, AC005046.1, U3, LAMB4, NRCAM, PNPLA8, RPL7P32, THAP5, DNAJB9, AC005487.1, AC002487.1, C7orf66, AC004014.2, AC004014.1, BUB3P1, AC002386.1.
- chr8:41,435,298–145,066,685, 1,608 genes, copy number 5–8 (broad region; genes not listed).
- chr11:69,641,156–70,436,584, 27 genes, copy number 20: CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:70,477,277–70,635,658, 3 genes, copy number 20: AP001271.1, AP001271.2, SHANK2-AS1.
- chr12:15,620,134–18,739,188, 37 genes, copy number 5: EPS8, RNU6-251P, AC073651.1, AC073651.2, STRAP, DERA, EGLN3P1, SLC15A5, MGST1, SUPT16HP1, AC007528.1, AC007552.1, LMO3, AC007552.2, AC007529.2, AC007529.1, SKP1P2, EEF1A1P16, AC092793.1, RNU6-837P, AC092110.1, RPL7P40, PSMC1P8, TIMM17BP1, AC048352.1, LINC02378, MIR3974, Y_RNA, RERGL, PIK3C2G, NDFIP1P1, AC092851.1, ZKSCAN7P1, PLCZ1, PSMC1P9, AC087242.1, CAPZA3.
- chr12:42,238,447–50,480,004, 244 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr12:85,781,892–86,838,904, 6 genes, copy number 5 (within-gene range 3–5): AC137768.1, RASSF9, NTS, MGAT4C, AC016993.1, AC139697.1.
- chr14:18,333,726–35,932,325, 633 genes, copy number 6–13 (within-gene range 4–13) (broad region; genes not listed).
- chr18:20,946,906–25,352,190, 98 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,139. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
